Surgical pathology report (de-identified scan), TCGA case TCGA-XH-A853, project TCGA-THYM (Thymoma), tissue source site BLN Baylor, specimen TCGA-XH-A853-01A (Primary Tumor).

[page 1 of 4]
----- SURGICAL PATHOLOGY -----

MEDICAL RECORD |

SURGICAL PATHOLOGY

PATHOLOGY REPORT

Laboratory:

Accession No.

Submitted by:

Date obtained:

Specimen (Received

A. THYMUS, FS

B. STATION 3 MEDIASTINAL LYMPH NODE

C. STATION 4L

D. THYMUS LYMPH NODE

E. MAMMARY FAT PAD

F. LEFT CHEST BIOPSY SITE

ICDO-3
Thymoma, type AB NOS 8582/1
Site: Thymus C37.9
JW 11/29/13

*** SUPPLEMENTARY REPORT HAS BEEN ADDED ***

*** REFER TO BOTTOM OF REPORT ***

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

Thymoma

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

Thymoma

Surgeon/physician:

PATHOLOGY REPORT

Laboratory:

Accession No.

Pathology Resident:

GROSS DESCRIPTION:

A. The specimen is received fresh for intraoperative consultation diagnosis and consists of a 110.6 g, 13.1 x 8.0 x 3.5 cm tissue comprising of a 5.0 x 4.5 x 3.5 cm, well-circumscribed mass along with attached adipose tissue and oriented with a short stitch indicating right superior horn, long stitch indicating the left superior horn and a medium sized purple stitch indicating the left lateral margin. The specimen is inked blue along the superficial superior aspect, black along the superficial inferior aspect, red along the deep superior aspect and green along the deep inferior aspect. The left lateral margin is submitted for frozen section diagnosis in cassette FsA1-A2.

The nodule is located 9.5 cm from the superior margin and abuts the right lateral, left lateral and inferior margins of the specimen. The nodule is serially sectioned to reveal a tan to mahogany-brown, solid, lobulated, homogeneous cut surface traversed by thin, white, fibrous trabecula. The surrounding fat reveals the presence of two tan-brown

[page 2 of 4]
to black rubbery lymph nodes displaying a tan-black to white cut surface.

Sections of the specimen are submitted as follows: Cassettes A1-A7- representative sections from the mass; A8- one whole bisected lymph node; A9- representative section of adipose tissue and one whole possible lymph node; A10- superior margin; A11- right superolateral margin.

FROZEN SECTION DIAGNOSIS:

FsA1-FsA2. Thymus, resection:

- LEFT LATERAL MARGIN - PROBABLY NEGATIVE FOR TUMOR (FIBROADIPOSE TISSUE AND LYMPHOID TISSUE WITH ANTHRACOTIC PIGMENT PRESENT)
- CANNOT ENTIRELY RULE OUT PRESENCE OF LYMPHOID TISSUE FROM THYMOMA

B. The specimen consists of a 0.5 x 0.4 x 0.3 cm, tan-brown to black, rubbery lymph node submitted in its entirety in cassette B.

C. The specimen consists of a 0.9 x 0.7 x 0.4 cm, tan-black to brown, rubbery lymph node, bisected and submitted in its entirety in cassette C.

D. The specimen consists of a 0.5 x 0.4 x 0.1 cm, tan-black to brown, possible lymph node, submitted in its entirety in cassette D.

E. The specimen consists of a 2.5 x 1.2 x 0.5 cm, tan-yellow to brown, lobulated piece of tissue which is serially sectioned to reveal a tan-yellow, lobulated cut surface. Representative section is submitted in cassette E.

F. The specimen consists of a 0.9 x 0.5 x 0.3 cm, skin-covered tissue. The specimen is inked, bisected and submitted in its entirety in cassette F.

MICROSCOPIC EXAM DIAGNOSIS:

A. Thymus, resection:

SPECIMEN: Thymus

PROCEDURE: Thymectomy

SPECIMEN INTEGRITY: Intact

SPECIMEN WEIGHT: 110.6 gm

TUMOR SIZE: 5.0 x 4.5 x 3.5 cm

HISTOLOGIC TYPE: Type AB thymoma

TUMOR EXTENSION: Not applicable

MARGINS: Margins uninvolved by tumor

TREATMENT EFFECT: Not applicable

LYMPH-VASCULAR INVASION: Not identified

REGIONAL LYMPH NODES: No regional lymph node metastases

NUMBER EXAMINED: 4

NUMBER INVOLVED: 0

PATHOLOGIC STAGING FOR THYOMAS (MODIFIED MASAOKA STAGE): Stage 1
(grossly microscopically encapsulated; includes microscopic

[page 3 of 4]
invasion into, but not through, the capsule)

IMPLANTS/DISTANT METASTASIS: Not present

ADDITIONAL PATHOLOGIC FINDINGS:

- Focal cystic change in tumor
- Involuted thymic tissue away from thymoma
- 1x1 mm parathyroid tissue in the superior margin

B. Station 3 mediastinal lymph node, excision:

- CALCIFIED NODULE, NEGATIVE FOR TUMOR

C. Station 4L lymph node, excision:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR

D. Thymus lymph node, excision:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR

E. Mammary fat pad, excision:

- MATURE ADIPOSE TISSUE WITH A TINY LYMPHOID AGGREGATE,
NEGATIVE FOR TUMOR

F. Left chest, biopsy site, excision:

- SKIN WITH DERMAL SCAR AND GIANT CELL REACTION, CONSISTENT WITH
THE PRIOR BIOPSY SITE

COMMENT: The thymoma is encapsulated; there is no tumor extension through the capsule. The tumor consists of spindle/oval and focally polygonal epithelial cells (positive for PCK and CK5/6 on immunohistochemistry) which are intermixed with T-cells (positive for CD3 and CD5 by immunohistochemistry). CD20 stains rare scattered B-cells. The neoplasm has a lobulated architecture, with traversing fibrous bands. Occasional Hassal's corpuscles are present.

Sections of the fibroadipose tissue away from the mass, including the superior and right superolateral margins, show involuted thymic tissue (with lymphoid component predominantly in the cortical area and epithelial component in the medullary area). Areas of cystic degeneration are present. By immunohistochemistry the epithelial component stains positive for PCK and CK5/6; and lymphoid component with CD3 and CD5. CD20 outlines B-cells in the germinal centers. The left lateral margin (which was submitted for frozen section) shows fibroadipose and lymphoid tissue, and no thymoma. Focal parathyroid tissue (1x1 mm) is identified in the superior margin (positive for chromogranin and AE1/3).

Mediastinal nodes show focal granulomas. The result of AFB and GMS special stains will be reported in an addendum.

Intradepartmental consultation:
the time of frozen section.

was notified at

Immunohistochemistry Disclaimer: "This test was developed and its performance characteristics determined by the
at the

It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should

[page 4 of 4]
not be regarded as investigational or for research. This Laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing."

SUPPLEMENTARY REPORT(S):

Supplementary Report Date:

*** SUPPLEMENTARY REPORT HAS BEEN ADDED/MODIFIED ***

(Added/Last released:

Signed by

The special stains (GMS, PAS, Mucin and AFB; performed on blocks A8 and C) are negative for fungal or acid fast organisms.

Qual/Syn/Immunos/Time/Block		☒

Source: NCI Genomic Data Commons file bf683ec0-9c0b-4bd3-80f2-cd20ec1dceaf (TCGA-XH-A853.A875F8DA-C1BE-47CA-8DC4-6105D72EF35B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).